Somatic mutation profile of tumor specimen TCGA-HT-7875-01A (aliquot TCGA-HT-7875-01A-11D-2395-08) from TCGA case TCGA-HT-7875, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 56.4 years (20,613 days).
Specimen TCGA-HT-7875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ba3a31f-e296-4456-9198-e71ffbe365ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7875-10A (Blood Derived Normal), aliquot TCGA-HT-7875-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff8e87d5-9007-43be-b241-bb3c0839b97f

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 19, Silent 9, Frame Shift Del 7, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARID4B | c.3136A>G p.T1046A | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1036445880, COSV51607073; called by muse, mutect2, varscan2
- CBLC | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs931299718, COSV54324213; called by muse, mutect2, varscan2
- CIC | c.2980C>T p.Q994* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as COSV50581347; called by muse, mutect2, varscan2
- COL7A1 | c.7013G>A p.R2338Q | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as rs201011691, COSV60393266; called by muse, mutect2, varscan2
- ELOA | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV69310084, COSV69310737; called by muse, mutect2, varscan2
- GABRA4 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51931169; called by muse, mutect2, varscan2
- ITGAL | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV63323234; called by muse, mutect2, varscan2
- MARCHF6 | c.2413A>T p.I805F | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); catalogued as COSV56883749, COSV56887207; called by muse, mutect2, varscan2
- MBD5 | c.2275G>A p.V759M | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377604964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53052320, COSV99490172; called by muse, mutect2
- OR1S1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58707752; called by muse, mutect2
- PHLDB1 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs782174338, COSV61880222; called by muse, mutect2
- SMARCB1 | c.991C>T p.R331C (on ENST00000263121; = p.R377C on NM_003073.5) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV51954280; called by muse, mutect2
- SMURF2 | c.778A>G p.R260G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52317083; called by muse, mutect2, varscan2
- TCF12 | c.1000_1001del p.Q334Dfs*3 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs730880017; called by pindel, varscan2
- TPO | c.1727C>A p.A576E | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764548001, CM1514366, COSV61094885, COSV61101015; called by muse, mutect2, varscan2
- UBA7 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs12486358, COSV61092763; called by muse, mutect2
- ZNF618 | c.2335G>A p.G779S (on ENST00000374126 / NM_001318042.2; = p.G686S on NM_133374.2) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55925151; called by muse, mutect2
- ZNF683 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763596899, COSV62873235; called by muse, mutect2, varscan2
- ATP8B4 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CEP89 | c.1592_1595del p.E531Gfs*7 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by pindel, varscan2
- CIC | c.3365_3366del p.V1122Gfs*28 | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | called by pindel, varscan2
- NCAM1 | c.1880_1881del p.S627Yfs*2 (on ENST00000316851 / NM_181351.5; = p.S617Yfs*2 on NM_000615.7) | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by pindel, varscan2
- PRPF18 | c.586_588del p.L196del | In Frame Del (DEL) | VAF 14/78 reads (18%) | called by pindel, varscan2
- SYCP2L | c.2043_2046del p.R682Sfs*11 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | called by pindel, varscan2
- TCF12 | c.1863_1865del p.H621del | In Frame Del (DEL) | VAF 32/52 reads (62%) | called by pindel, varscan2
- ZMYM2 | c.910_911del p.L304Ifs*8 | Frame Shift Del (DEL) | VAF 84/205 reads (41%) | called by mutect2, pindel, varscan2
- ZNF654 | c.1929_1932del p.T644Lfs*22 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel
- CLOCK | c.2475A>G p.Q825= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as COSV59403470; called by muse, mutect2, varscan2
- FUT4 | c.975C>T p.D325= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV62469657; called by muse, mutect2, varscan2
- GPR68 | c.609G>A p.A203= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs993119430, COSV53176908; called by muse, mutect2, varscan2
- INPP4B | c.1203C>T p.Y401= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV53719161, COSV53733774; called by muse, mutect2
- MED1 | c.2502A>T p.P834= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV56126778; called by muse, mutect2, varscan2
- NPFFR2 | c.630A>T p.I210= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV58151634; called by muse, mutect2, varscan2
- PRICKLE1 | c.678A>T p.G226= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV61544541; called by muse, mutect2, varscan2
- PSPC1 | c.1344C>T p.A448= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs777334737; called by muse, varscan2
- TAS2R13 | c.15G>A p.L5= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1387344007, COSV66831770; called by muse, mutect2, varscan2
